Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7647, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7647-01A (Primary Tumor).

[page 1 of 3]
ORIGINAL REPORT

SPECIMEN:

- A. Mass head of pancreas.
- B. Body of pancreas.
- C. Gallbladder.
- D. Bile duct margin.
- E. Hepatic artery node.
- F. Pancreas margin.
- G. Whipple's specimen.

CLINICAL HISTORY:

Pancreatic mass.

DIAGNOSIS:

- A: PANCREAS, (HEAD), BIOPSY:
- INVASIVE DUCTAL ADENOCARCINOMA.
- B: PANCREAS, (BODY), BIOPSY:
- CHRONIC PANCREATITIS.
- C: GALLBLADDER, CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS.
- ONE BENIGN LYMPH NODE (0/1).
- D: (BILE DUCT MARGIN), BIOPSY:
- CONSISTENT WITH LOW GRADE DYSPLASIA.
- E: LYMPH NODE, (HEPATIC ARTERY), EXCISION:
- METASTATIC ADENOCARCINOMA IS PRESENT (1/1).
- NO EXTRANODAL SOFT TISSUE EXTENSION IS SEEN.
- F: (PANCREAS MARGIN), BIOPSY:
- CONSISTENT WITH CHRONIC PANCREATITIS.
- G: PANCREATODUODENECTOMY WITH PARTIAL GASTRECTOMY:
- MODERATELY DIFFERENTIATED INVASIVE PANCREATOBILIARY DUCTAL ADENOCARCINOMA.
- TUMOR SIZE = 6.0 X 4.5 X 2.0 CM.
- TUMOR EXTENDS INTO THE PERIPANCREATIC SOFT TISSUE, AND EXTENDS TO LATERAL RESECTION MARGINS. THE DUODENAL MUCOSA IS INVOLVED.
- THE COMMON BILE DUCT MARGIN SHOWS LOW GRADE DYSPLASIA.
- THE PROXIMAL (GASTRIC) AND DISTAL (DUODENAL) MARGINS ARE FREE OF TUMOR.
- THE PANCREATIC RESECTION MARGIN DEMONSTRATES EXTRA-PANCREATIC CARCINOMA INVOLVING SMALL NERVES.
- LYMPHEVASCULAR AND PERINEURAL INVASION ARE IDENTIFIED.

[page 2 of 3]
DIAGNOSIS:

LYMPH NODES:

- METASTATIC CARCINOMA IS PRESENT IN ONE OF TWO COMMON BILE DUCT LYMPH NODES (1/2).
- METASTATIC CARCINOMA (WITH EXTRANODAL SOFT TISSUE EXTENSION) IS PRESENT IN FOUR OF NINE PERIDUODENAL LYMPH NODES (4/9).
- METASTATIC CARCINOMA (WITH EXTRANODAL SOFT TISSUE EXTENSION) IS PRESENT IN NINE OF NINE PERIPANCREATIC LYMPH NODES (9/9).
- THE NON-NEOPLASTIC PANCREAS HAS FEATURES OF CHRONIC PANCREATITIS.
- THE STOMACH SHOWS A MILD REACTIVE GASTRITIS.
- THE DUODENUM HAS ACUTE ISCHEMIC CHANGES DISTALLY.

GROSS DESCRIPTION:

- A. The specimen consists of one tiny piece of tan tissue measuring 0.3 cm. Embedded in toto as QS.
- B. The specimen consists of one core measuring 1.5 cm in length and 0.1 cm in diameter. Embedded in toto as QS.
- C. The specimen consists of an intact cholecystectomy specimen measuring 7.0 x 2.8 x 2.5 cm. There is a 0.4 cm possible cystic node identified submitted in C1. The cystic duct is 0.3 cm in diameter. There are no gallstones and the bile is thick and green. The mucosa is unremarkable and the wall thickness is 0.1 cm. There is a thickening near the cystic duct and a fold is present within the mucosa. Representative sections of duct and wall are submitted in C2. Section of thickened fold is submitted in C3.
- D. The specimen consists of a white duct with two lumens, the diameter of the first is 0.6 and the diameter of the other is 0.7 cm. The specimen is submitted in toto in cassette D.
- E. The specimen consists of a tan-brown node, 1.5 x 1.5 x 0.3 cm. Submitted in toto in cassette E1.

FINAL

[page 3 of 3]
HISTOPATHOLOGY REPORT

Inquiry Numbers:

Division Head:

GROSS DESCRIPTION:

F. The specimen consists of one piece of tan tissue measuring 0.9 x 0.4 x 0.1 cm. Embedded in toto as Q8.

G. The specimen consists of pancreaticoduodenectomy with partial gastrectomy. The entire specimen from proximal to distal measures 22.5 x 6.0 cm. and is painted with silver nitrate. The gastric segment measures 2.5 x 6.5 cm. and the duodenal segment is 20.0 x 6.0 cm. The pancreatic head measures 6.0 x 4.5 x 2.0 cm. The pancreatic resection margin is painted blue.

The gastric segment is unremarkable. The serosal surface of the duodenum has mild adhesions. The distal portion of the duodenal mucosa has a dusky appearance. Just by the ampulla of Vater, there is a 1.3 x 0.7 cm ulcerated lesion. Deep to this, there is a firm grey area that lies in continuity with the pancreatic head. The common bile duct is opened, and is patent. At the more proximal aspect, towards the cystic duct, it is hemorrhagic. The pancreatic duct, however, is not probe patent. Two lymph nodes are identified near the common bile duct, measuring 2.0 cm and 1.7 cm, respectively. On sectioning the pancreatic head, the cut surface is a tan-grey and firm with a central brown-red focus around the duct. The firm area is in continuity with the duodenal wall, and this abnormal area of pancreas measures approximately 3.0 x 2.2 x 1.1 cm.

Specimen is also submitted for the ampulla study, where a 3.0 x 3.0 cm block of duodenum with ampulla of Vater is taken and serially sectioned.

Specimen is submitted as follows:

- G1. enface common bile duct
- G2. larger common bile duct node
- G3. second common bile duct node bisected
- G4. proximal perpendicular resection margin
- G5. distal perpendicular resection margin
- G6. transition of possible normal duodenal mucosa to ischemic
- G7. representative section of normal duodenum
- G8. perpendicular section of the common bile duct with painted black margin
- G9. enface shave of pancreatic resection margin
- G10-11. transected first section furthest from the ampulla
- G12-13. following serial section
- G14-15. following serial section trisected

FINAL

Source: NCI Genomic Data Commons file 4799cf13-0c83-4a4b-8e60-13c5d70f493c (TCGA-IB-7647.AD7DAAD3-3D10-4EF1-BF00-89FCF18E471F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).